Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AL, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AL-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender:

Location:

Reported:

Ordering MD:

Facility:

Copy To:

Specimen(s) Received

1. Parathyroid: Right Upper
2. Parathyroid: Left lower parathyroid QS
3. Thyroid: Total thyroid stitch marks upper pole left lobe

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy
2. No pathological diagnosis: Parathyroid (left lower) biopsy
3. Multifocal papillary carcinoma, dominant follicular variant, 1.9 cm, right; severe chronic lymphocytic thyroiditis with reactive atypia and mild nodular hyperplasia: Thyroid
No pathological diagnosis: Parathyroids, 2, right and left perithyroidal
No pathological diagnosis: Lymph nodes, 14
-Total thyroidectomy specimen

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.5 cm
	3.1 cm
	1.5 cm
	Left lobe:
	3.6 cm
	2.0 cm
	1.3 cm
	Isthmus +/- pyramidal lobe:
	2.8 cm

100-0-3
carcinoma, papillary, follicular variant
8340/3
Site: thyroid, NOS C73.9
lw
10/21/11

[page 2 of 3]
Specimen Weight: 1.5 cm
0.8 cm
18.8 g
Tumor Focality: Multifocal, ipsilateral
Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 1.9cm
Additional dimension: 1.6 cm
Additional dimension: 1.5 cm
Histologic Type: Papillary carcinoma, follicular variant *per TSS, follicular variant = 100%*
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent minimal
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Isthmus
Tumor Size: Greatest dimension: 0.1cm
Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: None
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 14
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Thyroiditis, advanced
Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

3ross Description

1. The specimen labeled with the patient's name and as "Parathyroid: Right upper" contains a piece of tissue that measures 0.2 x 0.2 x 0.1 cm. It is frozen for intraoperative consultation.
- 1A frozen tissue resubmitted

[page 3 of 3]
2. The specimen labeled with the patient's name and as "left lower parathyroid" contains a piece of tissue that measures 0.4 x 0.2 x 0.1 cm and weighs 0.01 g. It is frozen for intraoperative consultation.

2A frozen tissue resubmitted

3. The specimen labeled with the patient's name and as "total thyroid stitch upper pole left lobe" consists of a thyroid gland that is oriented with a suture marking the left upper pole and weighs 18.76 g (fresh). The right lobe measures 4.5 cm SI x 3.1 cm ML x 1.5 cm AP, the left lobe measures 3.8 cm SI x 2.0 cm ML x 1.3 cm AP and the isthmus measures 2.8 cm SI x 1.5 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions and are painted with blue dye. No parathyroid glands or no lymph nodes are identified grossly. The right lobe contains a well delineated nodule that measures 1.6 cm SI x 1.9 cm ML x 1.5 cm AP. The left lobe contains an ill-defined, query nodule that measures 0.6 cm SI x 0.7 cm ML x 0.6 cm AP. Sections of right lobe nodule, one piece of normal tissue from the left lobe and one piece of thyroid from the right lobe are stored frozen. The remainder of the specimen is submitted as follows:

3A-K right lobe, superior to inferior

3C-D, E-F, G-H: one piece of tissue bisected in each set of blocks

3L-M isthmus

3M: one piece bisected

3N-S left lobe, superior to inferior

Quick Section Diagnosis

1. Parathyroid, right upper: parathyroid tissue
Called OR at

2. Parathyroid, left lower: parathyroid tissue
Called OR at

MD

Source: NCI Genomic Data Commons file 88dbfa2c-7cbb-4cdc-997a-cf73e2950d6c (TCGA-EM-A3AL.31921221-0B77-47EE-B989-3551A7C71FFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).